CCDI case PBCLVB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/955b29b8-c16c-4296-b649-9f2968bedc6e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,581 days).

Biospecimens (3 samples)
- Sample 0DUXNX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUXOZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVF8R: Tissue type: Tumor; Specimen type: Solid Tissue.
